Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A48U, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A48U-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

Patient:

[REDACTED]

....

Clinical Diagnosis & History:

y/o without any previous medial history was found to have large mass surrounding right renal artery and vein. Core biopsy shows leiomyosarcoma.

Specimens Submitted:

- 1: SP: Right lobe of liver bx (fs)
- 2: SP: Retroperitoneal sarcoma with right kidney

1CD0-3

leiomyosarcoma, NOS

889013

Site: retroperitoneum

C48.0

9-11-12

RD

DIAGNOSIS:

- 1) LIVER, RIGHT LOBE; BIOPSY:
- FOCAL PORTAL FIBROSIS.
- NO TUMOR SEEN.
- 2) RETROPERITONEAL SOFT TISSUE AND RIGHT KIDNEY; NEPHRECTOMY AND EXCISION OF MASS:
- LEIOMYOSARCOMA, HIGH GRADE, 30.0 CM GREATEST DIMENSION.
- TUMOR SHOWS 10% NECROSIS (GROSS ESTIMATE) AND COMES WITHIN 0.04 CM OF UNDESIGNATED SOFT TISSUE MARGIN.
- KIDNEY SHOWS SCATTERED SCLEROTIC GLOMERULI AND PATCHY INTERSTITIAL FIBROSIS AND CHRONIC INFLAMMATION (NO TUMOR).
- IMMUNOSTAINS ARE POSITIVE FOR SMA, DESMIN, AND CALDESMON; THERE IS NO STAINING FOR CD117.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Special Studies:

Result	Special Stain	Comment
	CD117	
	des	
	SMA	
	Caldesmon	
	NEG CONT	
	IMM RECUT	

** Continued on next page **

[page 2 of 3]
SURGICAL

----- Page 2 of 3

Gross Description:

1) The specimen is received fresh for frozen section, labeled "biopsy right lobe of liver", and consists of a 0.5 x 0.5 x 0.5 cm tan soft tissue fragment. Entirely submitted for frozen section.

Summary of sections:

FSC frozen section control

2) The specimen is received fresh, labeled "retroperitoneal sarcoma with right kidney", and consists of a 30.0 x 28.0 x 11.0 cm mass. The external surface is smooth and glistening. The external surface is inked black. The specimen is bisected to reveal a lobulated tan solid and whorled cut surface with areas of hemorrhage, myxoid changes and necrosis. There is also a kidney present which measures 14.0 x 5.0 x 4.0 cm (kidney and perirenal adipose tissue). It is bisected to reveal a grossly unremarkable cortex and medulla. Photograph is taken and a portion of the specimen is submitted for TPS.

Summary of section:

T tumor

K-kidney

M-soft tissue margin

VA-kidney (vein and artery)

Summary of Sections:

Part 1: SP: Right lobe of liver bx (fs)

Block	Sect.	Site	PCs
1	fsc		1

Part 2: SP: Retroperitoneal sarcoma with right kidney

Block	Sect.	Site	PCs
2	k		2
5	m		5
25	t		25
1	va		1

Intraoperative Consultation:

** Continued on next page **

[page 3 of 3]
SURGICAL

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1) FROZEN SECTION DIAGNOSIS: BENIGN LIVER; PREVIOUS REVIEWED

PERMANENT DIAGNOSIS: SAME.

** End of Report **

Source: NCI Genomic Data Commons file ff316fec-b12b-45db-9a07-7b6d8f7369ce (TCGA-DX-A48U.58F4A6F7-83C8-448E-8E9B-3653C9623029.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).